Gene-level copy-number profile of tumor specimen C3L-05638-02 from CPTAC case C3L-05638, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 77.0 years (28,112 days).
Specimen C3L-05638-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c8694573-a8d9-487e-8148-1346d02ade00.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05638-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/fb24ac3e-21a3-4a55-8199-fba678777705

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 9,210; copy number 2: 44,561; copy number 3: 4,071; copy number 4: 880; copy number 5: 151; copy number 6: 11.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,095,946–8,116,949, 2 genes: RPS3AP31, SNRPCP17.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,892,188–22,128,103, 10 genes (within-gene range 0–1): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:87,817,928–87,994,695, 7 genes (within-gene range 0–2): CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1.
- chr11:89,752,785–89,808,575, 8 genes: UBTFL2, AP003122.2, AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49.
- chr11:134,331,874–134,378,341, 1 gene: GLB1L2.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 162 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:72,558,744–72,828,200, 1 gene, copy number 5 (within-gene range 4–5): TYW1B.
- chr7:72,722,885–72,841,727, 5 genes, copy number 5: AC211469.2, AC211469.1, RN7SL377P, SBDSP1, RN7SL625P.
- chr7:73,440,406–73,522,293, 2 genes, copy number 5: BAZ1B, RNU6-1198P.
- chr7:73,732,569–73,865,890, 7 genes, copy number 5: RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4, METTL27, TMEM270.
- chr7:84,876,554–85,489,293, 8 genes, copy number 5: HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972.
- chr7:86,216,785–86,217,733, 1 gene, copy number 5: SOCS5P1.
- chr22:20,299,760–22,273,020, 138 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,354. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
